Somatic mutation profile of tumor specimen TARGET-10-PARMEG-09A (aliquot TARGET-10-PARMEG-09A-01D) from TARGET case TARGET-10-PARMEG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.1 years (3,687 days).
Specimen TARGET-10-PARMEG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71e80d9c-1c0b-4441-adef-1522bdf00a73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMEG-10A (Blood Derived Normal), aliquot TARGET-10-PARMEG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0bb3eb9-ece8-42f4-a992-9dd2b9baf381

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Intron 4, Silent 1, Frame Shift Ins 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL592490.1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69427551; called by muse, mutect2
- CILK1 | c.1853G>A p.R618Q (on ENST00000350082 / NM_001375397.1; = p.R611Q on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.143); catalogued as COSV63154557; called by muse, mutect2, varscan2
- DDX50 | c.2159G>A p.R720Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.885); catalogued as rs970465463, COSV65293059; called by muse, mutect2, varscan2
- ERC2 | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs746883356, COSV55657818; called by muse, mutect2, varscan2
- FAM234A | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.301); catalogued as rs757279121, COSV56993188; called by muse, mutect2, varscan2
- MSLN | c.1504G>A p.V502M (on ENST00000382862 / NM_013404.4; = p.V494M on NM_005823.6) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs770060839; called by muse, mutect2, varscan2
- PCDHAC1 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs781843995, COSV53836291; called by muse, mutect2, varscan2
- PKHD1L1 | c.12473C>A p.P4158H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV101006806, COSV65755644; called by muse, mutect2, varscan2
- ZNF521 | c.53A>C p.K18T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV64129816; called by muse, mutect2, varscan2
- APAF1 | c.1151C>A p.T384K (on ENST00000551964 / NM_181861.2; = p.T373K on NM_001160.3) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- C12orf40 | c.1865G>A p.C622Y | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSTF2T | c.1752_1753insGC p.Q585Afs*3 | Frame Shift Ins (INS) | VAF 55/108 reads (51%) | called by mutect2, varscan2
- EPRS1 | c.1976C>G p.P659R | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FBL | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.083); called by muse, mutect2
- HERC1 | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- KANSL1 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, varscan2
- LLGL1 | c.2789C>A p.S930* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- MACF1 | c.19922C>A p.T6641N (on ENST00000372915; = p.T4686N on NM_012090.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- OR4F15 | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCNX2 | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLAU | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRPF38B | c.1479C>A p.S493R | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2
- RYR2 | c.5365T>G p.S1789A | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR45 | c.770A>G p.D257G (on ENST00000376372 / NM_001029896.2; = p.D258G on NM_007075.3) | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- XYLT1 | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.026); called by mutect2, varscan2
- ZNF382 | c.392C>A p.T131K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, varscan2
- TRAK1 | c.1644C>A p.G548= (on ENST00000327628 / NM_001349247.2; = p.G490= on NM_014965.5) | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, varscan2
- AC022272.1 | n.123+1352C>A | Intron (SNP) | VAF 3/26 reads (12%) | called by muse, varscan2
- CACNA1B | c.530+9460G>A | Intron (SNP) | VAF 16/33 reads (48%) | catalogued as rs767849870; called by muse, mutect2, varscan2
- KCNMA1 | c.2267-7494C>A | Intron (SNP) | VAF 36/52 reads (69%) | called by muse, varscan2
- LINC01567 | n.430G>T | RNA (SNP) | VAF 4/33 reads (12%) | called by muse, varscan2
- POTEG | c.811-1067C>A | Intron (SNP) | VAF 3/15 reads (20%) | called by mutect2, varscan2
